Gene-level copy-number profile of tumor specimen TCGA-ER-A196-01A from TCGA case TCGA-ER-A196, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acral lentiginous melanoma, malignant; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 64.4 years (23,533 days).
Specimen TCGA-ER-A196-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.cc676eb2-77be-485d-9cb2-3ba7fc7a7ce3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ER-A196-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5cffe56c-a8f8-466f-ad24-38cca48b836d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,140; copy number 2: 52,493; copy number 3: 421; copy number 4: 2,085; copy number 5: 2; copy number 6: 11; copy number 7: 239; copy number 8: 251; copy number 9: 51; copy number 10: 21; copy number 11: 21; copy number 12: 8; copy number 13: 10; copy number 14: 30; copy number 17: 17; copy number 21: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ER-A196-01A-11D-A191-01): tumor purity 0.26, ploidy 2.13, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 673 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:4,497,449–23,586,224, 332 genes, copy number 7–21 (broad region; genes not listed).
- chr10:29,289,061–29,736,959, 10 genes, copy number 7: LYZL1, AL158167.1, SVIL-AS1, PTCHD3P1, SVIL, MIR604, SNORD115, MIR938, CKS1BP2, RNU6-908P.
- chr20:39,655,325–39,933,239, 3 genes, copy number 6: AL132981.1, AL118523.1, HSPE1P1.
- chr20:49,293,394–50,931,437, 44 genes, copy number 5–8 (within-gene range 2–8): KCNB1, AL035685.1, PTGIS, B4GALT5, RN7SL197P, SNRPFP1, RNU6-919P, SLC9A8, AL162615.1, SPATA2, Y_RNA, Metazoa_SRP, RNF114, KRT18P4, RNU6-147P, SNAI1, TRERNA1, UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271, RN7SL636P, COX6CP2, PTPN1, RN7SL672P, Y_RNA, AL133230.1, MIR645, RIPOR3, MIR1302-5, RPL36P2, RIPOR3-AS1, PARD6B, BCAS4, TMSB4XP6, ADNP, PSMD10P1.
- chr20:51,386,957–52,204,308, 11 genes, copy number 6–10 (within-gene range 2–10): NFATC2, MIR3194, ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1.
- chr20:52,972,358–53,495,330, 5 genes, copy number 6 (within-gene range 2–6): TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2.
- chr20:54,068,408–60,653,784, 120 genes, copy number 7–12 (within-gene range 2–12) (broad region; genes not listed).
- chr20:60,755,001–64,313,132, 148 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,140. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
